Somatic mutation profile of cancer-model specimen HCM-BROD-0415-C71-85R (3D Neurosphere, passage 9; aliquot HCM-BROD-0415-C71-85R-01D-A80U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0415-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.3 years (19,455 days).
Specimen HCM-BROD-0415-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1a0d7ba-cd1e-4158-93cc-04d13e966e64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0415-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0415-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8bde82b-0bf5-4ab4-b563-12ba5cd820c8

The open-access MAF lists 137 somatic variants for this specimen: 101 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 34, Frame Shift Del 8, Nonsense Mutation 7, In Frame Del 2, Intron 2, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 152/153 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 164/337 reads (49%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 192/436 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AMIGO2 | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 175/369 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs1001005665, COSV99873506; called by muse, varscan2
- ARHGAP21 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 85/85 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57605752; called by muse, mutect2, varscan2
- ATP8B3 | c.3824G>T p.G1275V | Missense Mutation (SNP) | VAF 56/536 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.116); catalogued as COSV100034602; called by muse, mutect2, varscan2
- ATRX | c.830del p.V277Afs*11 | Frame Shift Del (DEL) | VAF 186/493 reads (38%) | catalogued as COSV64880418; called by mutect2, pindel, varscan2
- BICDL1 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 178/388 reads (46%) | catalogued as COSV99985813; called by muse, mutect2, varscan2
- C7 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 110/239 reads (46%) | catalogued as rs1393459238, COSV57476232; called by muse, mutect2, varscan2
- C8orf34 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 123/249 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs750592151; called by muse, mutect2, varscan2
- CACNA1A | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 218/590 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs778912392; called by muse, mutect2, varscan2
- CCNF | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 120/389 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs951449600; called by muse, mutect2, varscan2
- CD209 | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 131/557 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.31); catalogued as COSV52659254; called by muse, mutect2, varscan2
- CHL1 | c.1363G>A p.V455M (on ENST00000397491 / NM_001253387.1; = p.V471M on NM_006614.4) | Missense Mutation (SNP) | VAF 94/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775477764, COSV56596958, COSV56598034; called by muse, mutect2, varscan2
- CXorf21 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV66763036; called by muse, mutect2, varscan2
- DLEU7 | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 92/266 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1339525667; called by muse, mutect2, varscan2
- DLGAP2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 370/830 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.192); catalogued as rs1291546030, COSV70094169; called by muse, mutect2
- DNAH10 | c.1862C>T p.P621L (on ENST00000409039; = p.P560L on NM_207437.3) | Missense Mutation (SNP) | VAF 168/321 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1350884916, COSV101292480; called by muse, mutect2, varscan2
- DNAH11 | c.8815T>A p.F2939I | Missense Mutation (SNP) | VAF 75/384 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs1266963849; called by muse, mutect2, varscan2
- DSCAM | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 127/234 reads (54%) | catalogued as rs1461810166, COSV68027236; called by muse, mutect2, varscan2
- FAM43A | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 28/646 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV61673112; called by muse, mutect2
- FCRL1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs551893022, COSV63824514; called by muse, mutect2, varscan2
- GABRA6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 123/295 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754862222, COSV50877427; called by muse, mutect2, varscan2
- GAS2L2 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 141/288 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.125); catalogued as rs782487976; called by muse, mutect2, varscan2
- HELZ2 | c.5314C>T p.P1772S (on ENST00000467148 / NM_001037335.2; = p.P1203S on NM_033405.3) | Missense Mutation (SNP) | VAF 304/540 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.059); catalogued as rs1232421413, COSV71296140; called by muse, varscan2
- INPP5J | c.1502C>T p.S501L (on ENST00000331075 / NM_001284285.2; = p.S133L on NM_001002837.2) | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs762702897, COSV58512130; called by muse, mutect2
- KIF2B | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 264/582 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs369005833, COSV52129723; called by muse, mutect2
- LATS2 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 129/337 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1217575272, COSV66880866; called by muse, mutect2, varscan2
- LCE2A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 171/438 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.059); catalogued as rs371432619; called by muse, mutect2, varscan2
- LETMD1 | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 173/353 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.12); catalogued as COSV99950252; called by muse, mutect2, varscan2
- LRRC18 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.939); catalogued as rs536518606, COSV53283082, COSV99629362; called by muse, mutect2, varscan2
- LTB4R | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 240/485 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs555617343; called by muse, mutect2, varscan2
- MBD3L2 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 223/579 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs772576142; called by muse, mutect2, varscan2
- MECOM | c.187G>A p.E63K (on ENST00000468789 / NM_001105078.4; = p.E251K on NM_004991.4) | Missense Mutation (SNP) | VAF 203/389 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs760397699, COSV52961960; called by muse, mutect2, varscan2
- MUC16 | c.19967C>A p.A6656D | Missense Mutation (SNP) | VAF 18/601 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.352); catalogued as COSV67483964; called by muse, mutect2
- NMBR | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766550244, COSV57802194; called by muse, varscan2
- NOBOX | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 176/569 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs750862438, COSV56194106; called by muse, mutect2, varscan2
- NUP160 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 289/609 reads (47%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV65855775; called by muse, mutect2, varscan2
- OR12D3 | c.589C>A p.L197I | Missense Mutation (SNP) | VAF 81/594 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.246); catalogued as rs751106658; called by muse, mutect2, varscan2
- OR4D6 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 210/429 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764578155, COSV55660383, COSV55660812; called by muse, mutect2, varscan2
- PGR | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 175/341 reads (51%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs150584881; called by muse, mutect2, varscan2
- PRAM1 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 233/589 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs531817922, COSV55316412; called by muse, mutect2, varscan2
- PTPRN2 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 158/876 reads (18%) | catalogued as rs532802114, COSV67026733; called by muse, mutect2, varscan2
- PXDNL | c.3319G>A p.V1107M | Missense Mutation (SNP) | VAF 214/469 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs770252979, COSV100683091; called by muse, mutect2, varscan2
- RFPL3 | c.197C>T p.S66L (on ENST00000249007 / NM_001098535.1; = p.S37L on NM_006604.2) | Missense Mutation (SNP) | VAF 340/672 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as rs370716010, COSV50748125; called by muse, mutect2
- RIMS2 | c.1411C>T p.R471W (on ENST00000666250 / NM_001348490.2; = p.R279W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 214/473 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566248680, COSV51698013; called by muse, mutect2, varscan2
- SMS | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 204/408 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as CM091187; called by muse, mutect2, varscan2
- STOX2 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 294/294 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1321820332; called by muse, mutect2, varscan2
- TBK1 | c.100T>G p.L34V | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1298720550; called by muse, mutect2, varscan2
- VSIR | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312702295; called by muse, mutect2, varscan2
- ZNF717 | c.1698T>A p.N566K | Missense Mutation (SNP) | VAF 156/502 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as rs1308578701; called by muse, mutect2, varscan2
- ZNFX1 | c.5179_5183del p.E1727Kfs*11 | Frame Shift Del (DEL) | VAF 201/415 reads (48%) | catalogued as rs776308098; called by mutect2, pindel, varscan2
- ABCA2 | c.3478C>T p.R1160C (on ENST00000614293; = p.R1130C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 416/703 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB10 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AC099489.1 | c.3017C>T p.T1006I | Missense Mutation (SNP) | VAF 147/325 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- AKAP9 | c.4504A>G p.T1502A | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANK2 | c.5662G>T p.E1888* | Nonsense Mutation (SNP) | VAF 67/603 reads (11%) | called by muse, mutect2, varscan2
- BCO2 | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 183/380 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CARS2 | c.811_812del p.I271Pfs*13 | Frame Shift Del (DEL) | VAF 80/227 reads (35%) | called by pindel, varscan2
- CCDC114 | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CHERP | c.1190T>C p.V397A | Missense Mutation (SNP) | VAF 177/630 reads (28%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CIT | c.2834T>C p.V945A | Missense Mutation (SNP) | VAF 122/231 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CLEC1B | c.353G>T p.R118M | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.431); called by muse, mutect2
- COL24A1 | c.2644G>T p.G882C | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.10705A>C p.K3569Q (on ENST00000297405 / NM_001363185.1; = p.K3400Q on NM_052900.3) | Missense Mutation (SNP) | VAF 205/385 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DLGAP4 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 238/510 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNAH3 | c.2660T>A p.M887K | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- EXTL3 | c.806del p.D269Vfs*69 | Frame Shift Del (DEL) | VAF 266/606 reads (44%) | called by mutect2, pindel, varscan2
- FAM71B | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 46/485 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FER1L6 | c.3774A>T p.K1258N | Missense Mutation (SNP) | VAF 153/401 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- FYTTD1 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 149/308 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCNT3 | c.999G>C p.W333C | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GDF9 | c.146_149del p.L49Cfs*4 | Frame Shift Del (DEL) | VAF 240/505 reads (48%) | called by mutect2, pindel, varscan2
- GGT6 | c.545C>T p.A182V (on ENST00000574154 / NM_001122890.3; = p.A150V on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 296/603 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- KIAA0408 | c.828_834del p.N276Kfs*16 | Frame Shift Del (DEL) | VAF 125/294 reads (43%) | called by mutect2, pindel, varscan2
- KIAA1328 | c.1734A>G p.*578Wext*7 | Nonstop Mutation (SNP) | VAF 80/190 reads (42%) | called by muse, mutect2, varscan2
- LDHD | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 307/583 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LINGO3 | c.1086_1094delinsTGT p.W362_Q365delinsCV | In Frame Del (DEL) | VAF 131/816 reads (16%) | called by pindel, varscan2*
- MACF1 | c.7889G>A p.R2630K | Missense Mutation (SNP) | VAF 90/250 reads (36%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 296/610 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC16 | c.27096T>G p.I9032M | Missense Mutation (SNP) | VAF 102/586 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- PHLDA2 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 368/768 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- PITX2 | c.336G>A p.M112I (on ENST00000354925 / NM_001204397.1; = p.M119I on NM_000325.6) | Missense Mutation (SNP) | VAF 103/709 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POU2F2 | c.213T>A p.D71E | Missense Mutation (SNP) | VAF 172/567 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PRKACA | c.297_315del p.F101Sfs*47 | Frame Shift Del (DEL) | VAF 64/442 reads (14%) | called by mutect2, pindel, varscan2
- PYHIN1 | c.668C>G p.T223R | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHOBTB3 | c.1390T>A p.Y464N | Missense Mutation (SNP) | VAF 24/506 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); called by muse, mutect2
- ROPN1B | c.284_301del p.K95_P100del | In Frame Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, varscan2
- SLC9A5 | c.2498C>A p.S833Y | Missense Mutation (SNP) | VAF 68/540 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNJ1 | c.430T>A p.S144T | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TBRG4 | c.1070T>G p.V357G | Missense Mutation (SNP) | VAF 123/415 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TNFRSF10D | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 253/441 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TOGARAM1 | c.4898-1G>A p.X1633_splice | Splice Site (SNP) | VAF 103/220 reads (47%) | called by muse, mutect2, varscan2
- TRIM24 | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 213/662 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC27 | c.306del p.Q102Hfs*40 | Frame Shift Del (DEL) | VAF 131/311 reads (42%) | called by mutect2, pindel, varscan2
- ULBP2 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 15/556 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.215); called by muse, mutect2
- VPS18 | c.2085C>G p.Y695* | Nonsense Mutation (SNP) | VAF 48/463 reads (10%) | called by muse, mutect2, varscan2
- ZC2HC1B | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 127/287 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF208 | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 110/366 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.083); called by mutect2, varscan2
- ZNF233 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 148/410 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ZNF717 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 154/499 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- ADCY1 | c.270G>A p.L90= | Silent (SNP) | VAF 60/1004 reads (6%) | catalogued as rs1376676829, COSV52041647; called by muse, mutect2
- ATP12A | c.2427C>T p.I809= | Silent (SNP) | VAF 205/375 reads (55%) | called by muse, mutect2, varscan2
- CCL4 | c.37C>T p.L13= | Silent (SNP) | VAF 43/528 reads (8%) | called by muse, mutect2
- CCN4 | c.192G>T p.L64= | Silent (SNP) | VAF 88/929 reads (9%) | called by muse, mutect2
- CD300C | c.90C>T p.T30= | Silent (SNP) | VAF 151/310 reads (49%) | catalogued as rs777405831, COSV58169934, COSV58170907; called by muse, mutect2, varscan2
- CHAF1A | c.729G>A p.Q243= | Silent (SNP) | VAF 212/555 reads (38%) | called by muse, mutect2, varscan2
- CHIC1 | c.108G>A p.S36= | Silent (SNP) | VAF 421/930 reads (45%) | called by muse, mutect2, varscan2
- CNGA3 | c.1614C>T p.F538= | Silent (SNP) | VAF 62/438 reads (14%) | catalogued as rs762984332, COSV55622386; called by muse, mutect2, varscan2
- CNTNAP2 | c.1293G>A p.V431= | Silent (SNP) | VAF 98/405 reads (24%) | called by muse, mutect2, varscan2
- DAB2IP | c.1212C>T p.C404= (on ENST00000408936; = p.C376= on NM_032552.3) | Silent (SNP) | VAF 233/417 reads (56%) | catalogued as rs896396352, COSV99406407; called by muse, mutect2, varscan2
- DMBT1 | c.720C>T p.G240= | Silent (SNP) | VAF 326/326 reads (100%) | catalogued as rs199795989, COSV57561961; called by muse, varscan2
- GATA6 | c.126G>A p.S42= | Silent (SNP) | VAF 348/706 reads (49%) | called by muse, mutect2, varscan2
- ITSN2 | c.2883G>C p.R961= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as rs1268928806; called by muse, varscan2
- JMJD1C | c.6781T>C p.L2261= | Silent (SNP) | VAF 162/163 reads (99%) | called by muse, mutect2, varscan2
- KIAA1109 | c.10041A>G p.T3347= | Silent (SNP) | VAF 104/291 reads (36%) | called by muse, mutect2, varscan2
- KLB | c.2220G>C p.L740= | Silent (SNP) | VAF 298/466 reads (64%) | called by muse, mutect2, varscan2
- LPA | c.2736G>A p.A912= | Silent (SNP) | VAF 166/310 reads (54%) | catalogued as rs1344439639; called by muse, mutect2, varscan2
- NDUFA13 | c.414C>T p.H138= | Silent (SNP) | VAF 148/344 reads (43%) | catalogued as rs755798891; called by muse, mutect2, varscan2
- OR4K5 | c.351G>A p.S117= | Silent (SNP) | VAF 141/486 reads (29%) | catalogued as rs765795652, COSV60002373, COSV60003499; called by muse, mutect2, varscan2
- RBMXL3 | c.987C>T p.Y329= | Silent (SNP) | VAF 402/772 reads (52%) | catalogued as rs1207892597, COSV100407257; called by muse, mutect2
- RMDN3 | c.537C>G p.A179= | Silent (SNP) | VAF 154/300 reads (51%) | called by muse, mutect2, varscan2
- RNF128 | c.366C>T p.R122= | Silent (SNP) | VAF 205/437 reads (47%) | catalogued as COSV55249509; called by muse, mutect2, varscan2
- RYR2 | c.8742G>A p.T2914= | Silent (SNP) | VAF 110/229 reads (48%) | catalogued as rs751520306, COSV63670560; called by muse, mutect2, varscan2
- SAP130 | c.957C>A p.T319= | Silent (SNP) | VAF 67/216 reads (31%) | called by mutect2, varscan2
- SLC6A20 | c.615C>T p.C205= | Silent (SNP) | VAF 202/382 reads (53%) | catalogued as rs779053318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOGA3 | c.2214G>T p.L738= | Silent (SNP) | VAF 16/600 reads (3%) | called by muse, mutect2
- TAP2 | c.1585C>T p.L529= | Silent (SNP) | VAF 74/549 reads (13%) | called by muse, mutect2, varscan2
- TFE3 | c.607C>T p.L203= | Silent (SNP) | VAF 90/684 reads (13%) | called by muse, mutect2, varscan2
- THSD7B | c.2712G>A p.K904= | Silent (SNP) | VAF 145/271 reads (54%) | catalogued as rs771913389; called by muse, mutect2, varscan2
- TPO | c.1260G>A p.A420= | Silent (SNP) | VAF 335/680 reads (49%) | catalogued as rs1358820098, COSV61094840; called by muse, varscan2
- TRIB2 | c.13A>C p.R5= | Silent (SNP) | VAF 120/291 reads (41%) | called by muse, mutect2, varscan2
- ZAR1 | c.282C>A p.L94= | Silent (SNP) | VAF 14/546 reads (3%) | catalogued as rs1285855054, COSV56718947; called by muse, mutect2
- ZNF546 | c.1359A>G p.Q453= | Silent (SNP) | VAF 227/678 reads (33%) | catalogued as rs1449211629; called by muse, mutect2, varscan2
- ZNF750 | c.1557A>G p.K519= | Silent (SNP) | VAF 153/460 reads (33%) | called by muse, mutect2, varscan2
- FBXL8 | c.153-194C>T | Intron (SNP) | VAF 178/335 reads (53%) | called by muse, mutect2, varscan2
- SYNE1 | c.1351-211_1351-205del | Intron (DEL) | VAF 93/258 reads (36%) | called by mutect2, pindel, varscan2
